Gene-level copy-number profile of tumor specimen TCGA-V4-A9EI-01A from TCGA case TCGA-V4-A9EI, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 78.2 years (28,562 days).
Specimen TCGA-V4-A9EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.b70fe2d1-ac09-42af-bd00-e92ae2a43628.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V4-A9EI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00ec3f03-b0a6-4bad-b0ce-771ac8679b18

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,431; copy number 2: 44,983; copy number 3: 1,744; copy number 4: 2,083; copy number 5: 45; copy number 9: 747; copy number 10: 787.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V4-A9EI-01A-11D-A39V-01): tumor purity 0.93, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,579 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:10,284,961–14,453,625, 45 genes, copy number 5 (within-gene range 4–5): AC006499.3, AC006499.5, AC006499.7, AC110768.2, ZNF518B, AC005599.1, AC110768.1, CLNK, AC084048.1, LINC02498, MIR572, RNPS1P1, HS3ST1, RNA5SP156, AC006230.1, AC025539.1, AC005699.1, LINC02360, AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1, AC007370.2, AC007370.1, U6, HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
